Somatic mutation profile of tumor specimen 0DLIFS from CCDI case PBBZLB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.3 years (1,938 days).
Specimen 0DLIFS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e432e38-43c9-413f-8a6f-f617f67480eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLIFB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/891ad085-4f6b-4570-8513-6d5fa6fcc582

The open-access MAF lists 61 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, 5'UTR 4, Intron 3, 3'UTR 2, Nonsense Mutation 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 346/388 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM120851, COSV52678166, COSV52736883, COSV52827473; called by muse, mutect2, varscan2
- BRINP2 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 135/597 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs140690261; called by muse, mutect2, varscan2
- CAMTA1 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 126/840 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV57920397; called by muse, mutect2, varscan2
- COL18A1 | c.3895G>A p.A1299T (on ENST00000359759 / NM_130444.3; = p.A1064T on NM_030582.4) | Missense Mutation (SNP) | VAF 102/426 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs539944051, COSV60594148; called by muse, mutect2, varscan2
- EML5 | c.1039C>G p.R347G | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.938); catalogued as COSV61352259; called by muse, mutect2, varscan2
- GPAM | c.2113T>C p.Y705H | Missense Mutation (SNP) | VAF 153/392 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV62082831; called by muse, mutect2, varscan2
- MYOT | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as rs778912259; called by muse, mutect2, varscan2
- PALB2 | c.3342G>C p.Q1114H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.271); catalogued as rs1567206753; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- RET | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 69/541 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1371891301, COSV60701709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STIL | c.2134G>C p.D712H | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1303716658; called by muse, mutect2, varscan2
- STYXL2 | c.2875A>G p.R959G | Missense Mutation (SNP) | VAF 176/744 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54806141; called by muse, mutect2, varscan2
- TTLL10 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 118/558 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs989054663; called by muse, mutect2, varscan2
- UBAP1 | c.320C>G p.T107S | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.031); catalogued as rs1271702139; called by muse, mutect2, varscan2
- UGT2B17 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV58501546; called by muse, mutect2, varscan2
- WDFY4 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 172/671 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57449490; called by muse, mutect2, varscan2
- AQP2 | c.659A>T p.N220I | Missense Mutation (SNP) | VAF 171/386 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- AVPR1B | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 73/416 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- BBC3 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, varscan2
- CAD | c.2790T>G p.F930L | Missense Mutation (SNP) | VAF 94/548 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- COL5A2 | c.4399C>T p.Q1467* | Nonsense Mutation (SNP) | VAF 32/768 reads (4%) | called by muse, mutect2
- CP | c.2748T>A p.F916L | Missense Mutation (SNP) | VAF 14/503 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- CRYZ | c.725G>C p.R242P | Missense Mutation (SNP) | VAF 59/380 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA2 | c.2306A>T p.E769V | Missense Mutation (SNP) | VAF 150/685 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GIPC1 | c.851-36_864del p.X284_splice | Splice Site (DEL) | VAF 115/179 reads (64%) | called by mutect2, pindel, varscan2
- IRGC | c.639C>G p.F213L | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF23 | c.1270T>G p.L424V | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.364); called by muse, mutect2
- LAMB1 | c.5061G>C p.K1687N | Missense Mutation (SNP) | VAF 97/252 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MYO3A | c.3914A>T p.K1305M | Missense Mutation (SNP) | VAF 124/896 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); called by muse, mutect2
- NCOA3 | c.3331T>G p.Y1111D | Missense Mutation (SNP) | VAF 157/1265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NETO1 | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PMFBP1 | c.752A>T p.Q251L | Missense Mutation (SNP) | VAF 161/515 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SCN1A | c.2149G>A p.A717T (on ENST00000303395 / NM_001202435.3; = p.A706T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2
- SIRT2 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2
- TOPAZ1 | c.1143G>C p.L381F | Missense Mutation (SNP) | VAF 219/247 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- USP45 | c.1576T>A p.S526T | Missense Mutation (SNP) | VAF 228/246 reads (93%) | SIFT tolerated (0.62); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ZFPM1 | c.529A>C p.T177P | Missense Mutation (SNP) | VAF 110/136 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF473 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 11/386 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ANGPT1 | c.1371A>T p.L457= | Silent (SNP) | VAF 11/288 reads (4%) | called by muse, mutect2
- BAHCC1 | c.4698C>T p.G1566= | Silent (SNP) | VAF 77/227 reads (34%) | catalogued as rs372621923; called by muse, mutect2, varscan2
- CNGA3 | c.180C>T p.S60= | Silent (SNP) | VAF 138/677 reads (20%) | catalogued as rs372760840; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL4A6 | c.3024C>A p.G1008= | Silent (SNP) | VAF 127/262 reads (48%) | called by muse, mutect2, varscan2
- FLRT1 | c.1791G>A p.K597= | Silent (SNP) | VAF 188/429 reads (44%) | catalogued as rs779193903, COSV99735219; called by muse, mutect2, varscan2
- GALNT17 | c.792G>A p.Q264= | Silent (SNP) | VAF 249/269 reads (93%) | called by muse, mutect2, varscan2
- GPR75 | c.1284C>T p.N428= | Silent (SNP) | VAF 133/673 reads (20%) | called by muse, mutect2, varscan2
- NCOA5 | c.1554T>A p.P518= | Silent (SNP) | VAF 313/466 reads (67%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.270G>C p.L90= | Silent (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- POU4F3 | c.885C>A p.I295= | Silent (SNP) | VAF 184/417 reads (44%) | catalogued as COSV57942173; called by muse, mutect2, varscan2
- SLC4A2 | c.603G>A p.A201= | Silent (SNP) | VAF 85/217 reads (39%) | catalogued as rs902364864; called by muse, mutect2, varscan2
- SLITRK5 | c.1902C>A p.T634= | Silent (SNP) | VAF 139/341 reads (41%) | catalogued as COSV100280499; called by muse, mutect2, varscan2
- THSD7B | c.573T>C p.C191= | Silent (SNP) | VAF 132/620 reads (21%) | catalogued as rs376814148; called by muse, mutect2, varscan2
- VAPB | c.522G>A p.K174= | Silent (SNP) | VAF 64/811 reads (8%) | called by muse, mutect2
- AL133304.2 | n.176C>G | RNA (SNP) | VAF 91/404 reads (23%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.-24C>T | 5'UTR (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- DSC2 | c.-76G>T | 5'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- FAM172A | c.*66G>A | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- L3MBTL3 | c.2136+82G>C | Intron (SNP) | VAF 54/125 reads (43%) | called by muse, mutect2, varscan2
- LPAR1 | c.-63A>C | 5'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- SERPINB6 | c.47+19_47+20insGTT | Intron (INS) | VAF 28/94 reads (30%) | called by pindel, varscan2
- SPRR2G | c.*39C>T | 3'UTR (SNP) | VAF 65/270 reads (24%) | called by muse, mutect2, varscan2
- SUCO | c.-94C>G | 5'UTR (SNP) | VAF 58/244 reads (24%) | catalogued as rs977688919; called by muse, mutect2, varscan2
- TMEFF2 | c.439+116G>A | Intron (SNP) | VAF 59/128 reads (46%) | called by muse, mutect2, varscan2
